Gene-level copy-number profile of specimen HCM-SANG-0292-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0292-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0292-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 16383e28-4009-439a-9cf2-c6791d38a1e9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0292-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,748 have no estimate.
https://portal.gdc.cancer.gov/files/19f4c8f2-1071-428b-b70a-bee00c4b0cb6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 575; copy number 1: 2,805; copy number 2: 8,391; copy number 3: 25,106; copy number 4: 13,927; copy number 5: 3,999; copy number 6: 3,245; copy number 7: 243; copy number 8: 340; copy number 10: 105; copy number 11: 13; copy number 12: 68; copy number 24: 4; copy number 27: 14; copy number 35: 20; copy number 43: 20.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:21,990,074–22,178,542, 13 genes (within-gene range 0–4): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P, AC010760.1, RPS8P10, IGHV1OR15-1, IGHV1OR15-3.
- chr15:22,194,885–22,202,734, 2 genes: IGHV1OR15-4, AC025884.3.
- chr21:13,038,160–14,658,821, 49 genes (within-gene range 0–2): ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1.
- chr21:16,754,519–16,873,691, 2 genes: AF130359.1, AF212831.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 827 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:174,919,082–177,610,330, 84 genes, copy number 8 (broad region; genes not listed).
- chr7:2,558,972–17,467,256, 218 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:157,539,056–158,587,823, 1 gene, copy number 7 (within-gene range 6–7): PTPRN2.
- chr7:157,739,010–159,233,377, 18 genes, copy number 7: AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:2,935,353–4,994,972, 1 gene, copy number 7 (within-gene range 2–8): CSMD1.
- chr8:3,409,133–3,426,587, 1 gene, copy number 7: AC026991.2.
- chr8:4,317,388–5,849,692, 15 genes, copy number 7–8: AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1.
- chr8:63,651,457–64,383,787, 7 genes, copy number 8 (within-gene range 2–8): AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2.
- chr8:64,798,804–67,746,378, 52 genes, copy number 8–11: AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1.
- chr8:76,966,768–77,014,028, 3 genes, copy number 8: MIR3149, PEX2, HIGD1AP18.
- chr8:79,259,402–81,924,348, 68 genes, copy number 12 (broad region; genes not listed).
- chr8:115,950,511–116,325,062, 1 gene, copy number 8 (within-gene range 2–8): LINC00536.
- chr8:116,289,622–128,564,679, 183 genes, copy number 8 (broad region; genes not listed).
- chr12:21,437,615–31,073,847, 163 genes, copy number 10–43 (within-gene range 4–43) (broad region; genes not listed).
- chr20:21,488,244–21,755,350, 12 genes, copy number 8: AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1.

Autosomal genes at a single copy (total copy number 1): 531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
